Gene-level copy-number profile of tumor specimen TCGA-78-7149-01A from TCGA case TCGA-78-7149, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 72.0 years (26,285 days).
Specimen TCGA-78-7149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7d8a2a65-b282-4789-9f9a-b7d599aa2562.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7149-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4becc982-3a49-484c-8b28-4eddc6b2ca33

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,387; copy number 2: 9,944; copy number 3: 21,248; copy number 4: 19,819; copy number 5: 1,556; copy number 6: 3,742; copy number 7: 1,123.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7149-01A-11D-2035-01): tumor purity 0.6, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,123 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,629,939–159,599,227, 75 genes, copy number 7 (broad region; genes not listed).
- chr1:162,316,852–192,957,713, 533 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:208,606,564–223,005,995, 236 genes, copy number 7 (broad region; genes not listed).
- chr1:237,042,184–248,919,946, 274 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:73,695,785–74,690,727, 5 genes, copy number 7 (within-gene range 2–7): CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
